Gene-level copy-number profile of tumor specimen TCGA-DD-A1EJ-01A from TCGA case TCGA-DD-A1EJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 71.2 years (26,009 days).
Specimen TCGA-DD-A1EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d8626116-e826-4620-9790-a8c5305bedcd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A1EJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/28e10373-32f6-4fef-9e7c-dc5aa2b0a01e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,773; copy number 2: 8,298; copy number 3: 21,257; copy number 4: 18,646; copy number 5: 8,668; copy number 6: 1,127; copy number 8: 14; copy number 9: 10; copy number 11: 14; copy number 14: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A1EJ-01A-11D-A151-01): tumor purity 0.75, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,471,924–184,734,130, 9 genes (within-gene range 0–1): AC099343.2, IRF2-DT, AC099343.3, LINC02427, AC099343.1, LINC02365, CASP3, PRIMPOL, CENPU.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 41 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:111,611,639–112,119,318, 14 genes, copy number 8 (within-gene range 4–8): ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2.
- chr4:139,411,927–139,740,745, 12 genes, copy number 11: AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16.
- chr4:139,763,080–139,794,433, 2 genes, copy number 11: AC108053.1, RN7SKP253.
- chr14:24,809,656–25,050,297, 3 genes, copy number 14 (within-gene range 5–14): STXBP6, AL161663.2, AL161663.1.
- chr14:31,018,446–31,420,550, 10 genes, copy number 9 (within-gene range 2–9): AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2.

Autosomal genes at a single copy (total copy number 1): 1,773. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
